Gene-level copy-number profile of tumor specimen ALCH-B2TE-TTP1-A from ALCHEMIST case ALCH-B2TE, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 62.7 years (22,899 days).
Specimen ALCH-B2TE-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 53b96b49-ea72-4159-b391-a160632ea68f.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B2TE-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,707 have no estimate.
https://portal.gdc.cancer.gov/files/1df24015-083e-45f8-bbef-c510f99afff8

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 25; copy number 1: 5,760; copy number 2: 52,588; copy number 3: 526; copy number 4: 17.

Homozygous deletions (total copy number 0; autosomes only): 21 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:149,191,043–149,226,238, 2 genes: AC004890.1, ZNF282.
- chr8:46,028,804–46,028,892, 1 gene: AC118650.1.
- chr11:77,066,961–77,215,241, 3 genes: CAPN5, OMP, MYO7A.
- chr16:1,911,475–1,918,415, 1 gene: HS3ST6.
- chr16:83,929,796–83,931,223, 1 gene (within-gene range 0–2): AC009119.2.
- chr20:35,558,737–35,607,562, 2 genes: FER1L4, RPL37P1.
- chr22:21,640,844–21,700,015, 11 genes (within-gene range 0–2): AP000553.3, SDF2L1, AP000553.1, MIR301B, MIR130B, AP000553.5, AP000553.6, AP000553.7, AP000553.4, AP000553.2, PPIL2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 3,105. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
